Somatic mutation profile of tumor specimen TCGA-29-2429-01A (aliquot TCGA-29-2429-01A-01D-1526-09) from TCGA case TCGA-29-2429, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.8 years (29,156 days).
Specimen TCGA-29-2429-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cadb8e6-6756-48d9-a110-61e9145411d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-2429-10A (Blood Derived Normal), aliquot TCGA-29-2429-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b76a839-de29-4e65-a2fb-7770aa7ce570

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 56, Silent 25, Frame Shift Del 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3 | c.332C>G p.T111S | Missense Mutation (SNP) | VAF 168/247 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.145); catalogued as COSV99865538; called by muse, mutect2
- ACAD8 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV55542303; called by muse, mutect2, varscan2
- ADGRE2 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 88/1127 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.389); catalogued as rs1259898636, COSV100216008; called by muse, mutect2
- AP3B1 | c.333T>A p.D111E | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV54891234; called by muse, mutect2, varscan2
- ATM | c.5783T>G p.F1928C | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV53768850; called by muse, mutect2, varscan2
- ATP13A2 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV58700913, COSV58703180; called by muse, varscan2
- BSDC1 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61983078; called by muse, mutect2, varscan2
- C4A | c.2741T>C p.V914A | Missense Mutation (SNP) | VAF 84/679 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV71178760; called by muse, mutect2, varscan2
- CD96 | c.1741G>A p.E581K (on ENST00000283285 / NM_198196.3; = p.E565K on NM_005816.5) | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1242034669, COSV51914829; called by muse, mutect2, varscan2
- CDON | c.3828C>A p.S1276R (on ENST00000392693 / NM_001243597.2; = p.S1253R on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/371 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as COSV55001605; called by muse, mutect2, varscan2
- CHD1 | c.3861G>A p.K1287= | Splice Region (SNP) | VAF 12/68 reads (18%) | catalogued as COSV52344000; called by mutect2, varscan2
- CLDN3 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101230844; called by muse, mutect2
- DMD | c.10442A>G p.Q3481R | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.062); catalogued as rs368594777, COSV58944573; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DPYSL2 | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60784986; called by muse, mutect2, varscan2
- DXO | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV61714858, COSV61715269; called by muse, mutect2, varscan2
- EIF4G1 | c.4696A>G p.S1566G (on ENST00000346169 / NM_198241.3; = p.S1371G on NM_004953.5) | Missense Mutation (SNP) | VAF 72/423 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV59993356; called by muse, mutect2, varscan2
- FLRT2 | c.1348T>C p.Y450H | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV58148613; called by muse, mutect2, varscan2
- GAL3ST3 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as rs762977263, COSV61748818; called by muse, mutect2, varscan2
- GDPD4 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 134/453 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1168510033, COSV60022140; called by muse, mutect2, varscan2
- GOLGA5 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV50835204; called by muse, mutect2, varscan2
- GPATCH1 | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 85/602 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV50123801; called by muse, mutect2, varscan2
- GRID2 | c.3008G>C p.R1003P | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs773192553, COSV56253710, COSV56265967; called by muse, mutect2, varscan2
- GTF2F2 | c.154A>C p.T52P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV61242310; called by muse, mutect2, varscan2
- HECW2 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 56/573 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647110, COSV99648899; called by muse, mutect2
- HS2ST1 | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63352377; called by muse, mutect2, varscan2
- HYDIN | c.2260G>T p.G754W | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55496571; called by muse, mutect2, varscan2
- IGHMBP2 | c.2822G>A p.R941Q | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373408947; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1540C>A p.R514S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV67347871, COSV67348035; called by muse, mutect2, varscan2
- KIRREL1 | c.2113C>T p.R705* | Nonsense Mutation (SNP) | VAF 19/129 reads (15%) | catalogued as COSV63290187; called by muse, mutect2, varscan2
- LAMA2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70353549; called by muse, mutect2, varscan2
- LAMA2 | c.7070G>T p.W2357L | Missense Mutation (SNP) | VAF 61/540 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs761714859, COSV70353551; called by muse, mutect2, varscan2
- LHCGR | c.1845T>A p.N615K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54301904; called by muse, mutect2, varscan2
- LINGO4 | c.1472G>C p.G491A | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63216132; called by muse, mutect2, varscan2
- LLGL1 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV57500189; called by muse, mutect2, varscan2
- LPAR3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779454790, COSV65452700; called by muse, mutect2, varscan2
- MAP3K5 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62891608; called by muse, mutect2, varscan2
- MAP4 | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV64243928; called by muse, mutect2, varscan2
- MCCC1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 150/449 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.142); catalogued as COSV99659685; called by muse, mutect2
- NRDE2 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 114/245 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs560359168, COSV62964465; called by muse, mutect2, varscan2
- OR10K1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56873740; called by muse, mutect2, varscan2
- OSTM1 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs766277207, COSV51971059; called by muse, mutect2, varscan2
- POGZ | c.455C>G p.T152R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV55034598, COSV55040954; called by muse, mutect2, varscan2
- POMT2 | c.1654-2A>T p.X552_splice | Splice Site (SNP) | VAF 116/935 reads (12%) | catalogued as COSV55073459; called by muse, mutect2, varscan2
- PSIP1 | c.1210C>G p.R404G | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1259531145, COSV66253598, COSV66255063; called by muse, mutect2, varscan2
- PTER | c.980G>T p.R327I | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1416308990, COSV100126533, COSV54346967; called by muse, mutect2, varscan2
- RBM47 | c.704T>A p.I235N | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV55942012; called by muse, mutect2, varscan2
- RNF128 | c.637G>C p.V213L (on ENST00000255499 / NM_194463.2; = p.V187L on NM_024539.3) | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV55253949; called by muse, mutect2, varscan2
- ROS1 | c.2976C>G p.F992L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV63851964, COSV63860483; called by muse, mutect2, varscan2
- SCN10A | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs147246725; called by muse, mutect2, varscan2
- SCN1A | c.2244G>A p.W748* (on ENST00000303395 / NM_001202435.3; = p.W737* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as rs1553543340, COSV57684073; called by muse, mutect2, varscan2
- SCN2A | c.4699A>G p.N1567D | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51853111; called by muse, mutect2, varscan2
- SERPINB9 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs780661299, COSV66232926; called by muse, mutect2, varscan2
- SLC14A2 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV54913736; called by muse, mutect2, varscan2
- SOAT2 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs891592655, COSV56861029; called by muse, mutect2, varscan2
- SPG11 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs780840118, COSV56000944; called by muse, mutect2, varscan2
- TESMIN | c.622A>T p.N208Y | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV54834752; called by muse, mutect2, varscan2
- TSHZ2 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs200855096, COSV61587815; called by muse, mutect2, varscan2
- ZNF626 | c.1574T>G p.L525R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV101656981; called by muse, mutect2
- ZSCAN2 | c.1815G>C p.Q605H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV57572608; called by muse, mutect2, varscan2
- A1CF | c.1708_1709del p.L570Sfs*7 (on ENST00000373993 / NM_138932.2; = p.L562Sfs*7 on NM_014576.4) | Frame Shift Del (DEL) | VAF 74/366 reads (20%) | called by mutect2, pindel, varscan2
- A1CF | c.857del p.L286* | Frame Shift Del (DEL) | VAF 54/208 reads (26%) | called by mutect2, pindel, varscan2
- ABCC9 | c.4243dup p.D1415Gfs*2 | Frame Shift Ins (INS) | VAF 28/124 reads (23%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.3281_3287del p.N1094Tfs*8 (on ENST00000286628 / NM_001161352.2; = p.N1036Tfs*8 on NM_002247.4) | Frame Shift Del (DEL) | VAF 41/105 reads (39%) | called by mutect2, pindel, varscan2
- MED29 | c.91G>C p.A31P (on ENST00000615911; = p.A10P on NM_017592.4) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.147); called by muse, mutect2
- TP53 | c.377_400del p.Y126_M133del | In Frame Del (DEL) | VAF 63/114 reads (55%) | called by mutect2, pindel, varscan2
- BRD4 | c.2031G>A p.K677= | Silent (SNP) | VAF 50/492 reads (10%) | catalogued as rs748300253, COSV54593203; called by muse, mutect2
- CHST11 | c.711C>T p.F237= | Silent (SNP) | VAF 136/577 reads (24%) | catalogued as COSV57985343; called by muse, mutect2, varscan2
- CLDN3 | c.393C>A p.T131= | Silent (SNP) | VAF 46/284 reads (16%) | catalogued as rs1554626685, COSV101230845; called by muse, mutect2
- DRG2 | c.558C>A p.G186= | Silent (SNP) | VAF 46/169 reads (27%) | catalogued as COSV56729236; called by muse, mutect2, varscan2
- EXOSC4 | c.513G>A p.A171= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs147555477; called by muse, mutect2, varscan2
- FBXO40 | c.1089T>C p.L363= | Silent (SNP) | VAF 46/202 reads (23%) | catalogued as COSV57526913; called by muse, mutect2, varscan2
- GLI3 | c.2658G>A p.P886= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs375355919, COSV67893993; called by muse, mutect2, varscan2
- HERC2 | c.5223G>A p.Q1741= | Silent (SNP) | VAF 44/199 reads (22%) | catalogued as COSV55345411; called by muse, mutect2, varscan2
- ITGAD | c.387G>A p.S129= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs750617929, COSV66757365; called by muse, mutect2, varscan2
- KCNE1 | c.300G>C p.L100= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV61607085, COSV61607371; called by muse, mutect2, varscan2
- KIF1C | c.1800G>A p.P600= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as rs200771979; called by muse, mutect2, varscan2
- MBD4 | c.906G>C p.V302= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV51445667; called by muse, mutect2, varscan2
- NIN | c.2610G>C p.A870= | Silent (SNP) | VAF 78/263 reads (30%) | catalogued as COSV99813489; called by muse, mutect2, varscan2
- NKX2-4 | c.687G>T p.T229= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV61085826; called by muse, mutect2, varscan2
- OR10G7 | c.186C>A p.T62= | Silent (SNP) | VAF 172/944 reads (18%) | catalogued as COSV57868559; called by muse, mutect2, varscan2
- OR10X1 | c.414C>A p.R138= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV63767891; called by muse, mutect2, varscan2
- PRKD2 | c.1437C>T p.G479= | Silent (SNP) | VAF 86/327 reads (26%) | catalogued as COSV52185366; called by muse, mutect2, varscan2
- RHBG | c.285C>T p.L95= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1412004459, COSV54809291; called by muse, mutect2, varscan2
- SCN2A | c.4227A>G p.G1409= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV99331603; called by muse, mutect2
- SUN5 | c.105C>T p.S35= | Silent (SNP) | VAF 104/590 reads (18%) | catalogued as COSV50069689; called by muse, mutect2, varscan2
- TBX3 | c.711T>C p.G237= | Silent (SNP) | VAF 104/480 reads (22%) | catalogued as COSV57474842; called by muse, mutect2, varscan2
- TLDC2 | c.378C>G p.L126= | Silent (SNP) | VAF 146/772 reads (19%) | catalogued as COSV54115142, COSV54115467; called by muse, mutect2, varscan2
- TLN2 | c.576G>A p.T192= | Silent (SNP) | VAF 95/311 reads (31%) | catalogued as rs1338733842, COSV60890239; called by muse, mutect2, varscan2
- TRIM39 | c.1398C>T p.A466= | Silent (SNP) | VAF 157/330 reads (48%) | catalogued as rs140287492; called by muse, mutect2, varscan2
- TTN | c.9834G>T p.L3278= (on ENST00000591111; = p.L3232= on NM_003319.4) | Silent (SNP) | VAF 38/224 reads (17%) | catalogued as COSV60288460; called by muse, mutect2, varscan2
